Gene-level copy-number profile of tumor specimen ALCH-B2XG-TTP1-A from ALCHEMIST case ALCH-B2XG, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 70.2 years (25,638 days).
Specimen ALCH-B2XG-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 87fc020e-003a-4648-a726-ec9fcecbb1ad.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2XG-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,720 have no estimate.
https://portal.gdc.cancer.gov/files/ebb4e157-0947-45e7-a4e6-77883fd97d35

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 1,616; copy number 1: 28,054; copy number 2: 25,327; copy number 3: 2,345; copy number 4: 529; copy number 5: 863; copy number 6: 169.

Homozygous deletions (total copy number 0; autosomes only): 1,091 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:7,368,942–7,441,554, 3 genes (within-gene range 0–1): CAMTA1-IT1, CAMTA1-AS2, CAMTA1-AS1.
- chr2:91,617,160–91,659,972, 1 gene (within-gene range 0–2): LSP1P4.
- chr3:75,384,059–75,599,673, 12 genes: AC139453.2, LSP1P2, AC139453.1, ALG1L6P, FAM86DP, LINC02018, ENPP7P2, SNRPCP10, AC133041.1, RPS3AP15, AC108724.1, OR7E121P.
- chr9:8,936,079–9,803,784, 4 genes (within-gene range 0–1): AL596451.1, RPS26P3, RN7SL5P, AL513422.1.
- chr9:61,190,003–61,627,683, 9 genes: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D.
- chr10:79,703,227–79,714,681, 1 gene (within-gene range 0–1): NUTM2B.
- chr12:111,304,142–111,339,621, 2 genes (within-gene range 0–1): MIR6760, RNA5SP373.
- chr16:46,469,341–58,734,342, 332 genes (within-gene range 0–1) (broad region; genes not listed).
- chr16:66,301,809–90,047,773, 727 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 3,579 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,975,087–149,812,373, 187 genes, copy number 3 (broad region; genes not listed).
- chr2:90,114,838–90,115,402, 1 gene, copy number 3 (within-gene range 1–3): IGKV3D-15.
- chr2:242,088,633–242,175,634, 4 genes, copy number 4: LINC01881, CICP10, SEPTIN14P2, RPL23AP88.
- chr3:158,105,855–164,171,556, 70 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr3:167,956,311–198,123,232, 587 genes, copy number 4–6 (broad region; genes not listed).
- chr5:58,198–45,895,970, 679 genes, copy number 5–6 (broad region; genes not listed).
- chr6:157,289,025–164,348,644, 112 genes, copy number 3–4 (broad region; genes not listed).
- chr7:37,032–2,664,802, 71 genes, copy number 3 (broad region; genes not listed).
- chr7:155,611,231–155,645,205, 1 gene, copy number 3 (within-gene range 1–3): AC009403.1.
- chr8:36,004,316–37,095,390, 17 genes, copy number 3: AC124290.2, AC124290.3, MTCYBP19, MTND6P19, MTND5P41, AP006245.1, RNU6-533P, AP006245.2, AC090809.1, RPL23P10, RNA5SP264, KCNU1, AC124076.1, TPT1P8, AC090453.1, AC092818.1, SMARCE1P4.
- chr8:38,030,534–39,730,065, 45 genes, copy number 4–6: EIF4EBP1, AP006545.1, AP006545.2, ASH2L, RNU6-988P, AC084024.1, STAR, AC084024.3, LSM1, RNU6-323P, BAG4, AC084024.2, AC084024.4, DDHD2, PLPP5, NSD3, AC087362.2, AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1, RNF5P1, AC016813.1, TACC1, Y_RNA, AC067817.1, AC067817.2, PLEKHA2, AC108863.1, HTRA4, TM2D2, ADAM9, SNORD38D, ADAM32, RPL3P10, AC105185.1, ADAM5, ADAM3A, AC123767.1, ADAM18.
- chr8:43,292,483–43,674,591, 14 genes, copy number 3: POTEA, RNU6-104P, AC022616.8, AC022616.6, U3, AC134698.1, AC134698.4, AC134698.3, SNX18P27, AC134698.5, CYP4F44P, AC134698.2, AC139365.2, AC139365.1.
- chr8:87,974,165–145,066,685, 879 genes, copy number 3–4 (broad region; genes not listed).
- chr12:12,310–28,581,511, 714 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr12:29,142,969–34,249,958, 116 genes, copy number 3 (broad region; genes not listed).
- chr14:21,797,287–22,482,959, 71 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr14:22,547,506–22,552,156, 1 gene, copy number 3: TRAC.
- chr22:29,883,169–30,207,195, 10 genes, copy number 3–4: MTMR3, RNU6-331P, AC003681.1, MIR6818, HORMAD2-AS1, CNN2P1, HORMAD2, AC003071.1, RPS3AP51, AC002378.1.

Autosomal genes at a single copy (total copy number 1): 26,476. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
